Somatic mutation profile of tumor specimen C3N-01645-02 (aliquot CPT0088410009) from CPTAC case C3N-01645, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 71.9 years (26,258 days).
Specimen C3N-01645-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16ada2a7-e59b-4f24-90b2-40d57a0d3d08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01645-31 (Blood Derived Normal), aliquot CPT0088470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ea9a3ce-7603-44fd-b9a5-4da4c7ddeaab

The open-access MAF lists 135 somatic variants for this specimen: 90 protein-altering or splice-affecting, 29 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 29, Splice Site 8, 3'UTR 6, Intron 5, Frame Shift Del 4, Nonsense Mutation 3, RNA 3, 5'Flank 2, Frame Shift Ins 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>T p.X51_splice | Splice Site (SNP) | VAF 70/287 reads (24%) | hotspot (GDC flag); catalogued as rs730881677, CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 64/318 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOT8 | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs778763267; called by muse, mutect2, varscan2
- ANKRD35 | c.2098G>A p.G700S | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs782573218, COSV100841705; called by muse, mutect2
- APOB | c.2968G>A p.A990T | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs139434026; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2
- BSN | c.7457G>A p.R2486Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs750422766; called by muse, mutect2, varscan2
- CATSPER1 | c.92A>G p.H31R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs144423333; called by muse, mutect2, varscan2
- CDH7 | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV59894152; called by muse, mutect2
- CLMN | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs189680603; called by muse, mutect2, varscan2
- COL6A3 | c.2704C>A p.L902I | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.087); catalogued as COSV55088855; called by muse, mutect2
- CYP19A1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 19/438 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV99548408; called by muse, mutect2
- DGKZ | c.2629C>T p.R877C (on ENST00000454345 / NM_001105540.2; = p.R689C on NM_003646.4) | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236003340; called by muse, mutect2
- DLL1 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 17/480 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.16); catalogued as rs778035057; called by muse, mutect2
- ERC2 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV55608835; called by muse, mutect2
- FOXA3 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.042); catalogued as rs746646287, COSV56215998; called by muse, mutect2, varscan2
- FTSJ3 | c.1360_1362del p.D454del | In Frame Del (DEL) | VAF 23/164 reads (14%) | catalogued as rs747572988; called by pindel, varscan2
- GNB2 | c.97-1G>C p.X33_splice | Splice Site (SNP) | VAF 15/424 reads (4%) | catalogued as COSV99310260; called by muse, mutect2
- GTF3C1 | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 47/413 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs376123103; called by muse, mutect2, varscan2
- HARS2 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 44/489 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs752472621, COSV51226807; ClinVar: uncertain significance; called by muse, mutect2
- IARS2 | c.2186C>T p.T729I | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs1245663438; called by muse, mutect2
- IL7R | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 15/396 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.072); catalogued as rs1342028323, COSV57408543, COSV57415317, COSV99073412; called by muse, mutect2
- ITGB4 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1385099868, COSV99564094; ClinVar: uncertain significance; called by muse, mutect2
- LIFR | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771210130; called by muse, mutect2, varscan2
- LRRC7 | c.804G>T p.K268N (on ENST00000651989 / NM_001370785.2; = p.K235N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50511350; called by muse, mutect2
- MTOR | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs759750826, COSV63877783; called by muse, mutect2, varscan2
- MYOD1 | c.631-1G>A p.X211_splice | Splice Site (SNP) | VAF 7/127 reads (6%) | catalogued as COSV51455791; called by muse, mutect2
- MYOM2 | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs768869425; called by muse, mutect2, varscan2
- NIPA2 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV61682716; called by muse, mutect2, varscan2
- NPAS1 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs747338082; called by muse, mutect2
- OR2M3 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV71759214; called by muse, mutect2, varscan2
- OR6M1 | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as COSV58434070; called by muse, mutect2
- PIK3CG | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs747427177, COSV100782440; called by muse, mutect2, varscan2
- PNN | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.359); catalogued as rs1306557706; called by muse, mutect2
- RBM47 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1479498250; called by muse, mutect2
- RYR1 | c.2780C>T p.T927M | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751728775, COSV62093472; called by muse, mutect2
- SIX3 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 42/390 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV53227890; called by muse, mutect2, varscan2
- SMPDL3B | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs544282310, COSV65871359; called by muse, mutect2, varscan2
- SRC | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1328205125, COSV62439817; called by muse, mutect2
- SRCIN1 | c.2648C>T p.T883M (on ENST00000621492; = p.T849M on NM_025248.3) | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs767903662; called by muse, mutect2
- TLR1 | c.2232C>G p.H744Q | Missense Mutation (SNP) | VAF 12/327 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as rs1560455637; called by muse, mutect2
- USP20 | c.79A>C p.K27Q | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs777515945; called by muse, mutect2, varscan2
- WHRN | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214411230; called by muse, mutect2
- YARS1 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1385295171, COSV100993335; called by muse, mutect2
- AGRN | c.1091A>T p.Y364F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ANKRD34C | c.435A>T p.K145N | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ATF1 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- ATP7A | c.2004G>A p.M668I | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC144A | c.3098C>A p.A1033D | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- CCDC168 | c.2972G>C p.R991T | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.208); called by muse, mutect2
- CKB | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2
- CLEC16A | c.2344del p.H782Ifs*37 | Frame Shift Del (DEL) | VAF 59/373 reads (16%) | called by mutect2, pindel, varscan2
- CLVS1 | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2
- COL4A5 | c.2893G>C p.E965Q | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- CSMD3 | c.3275A>G p.N1092S (on ENST00000297405 / NM_001363185.1; = p.N988S on NM_052900.3) | Missense Mutation (SNP) | VAF 98/436 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- DNAJC7 | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- EDAR | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EOMES | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.074); called by muse, mutect2
- EPB41L3 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- FAT1 | c.7931dup p.N2645Efs*5 | Frame Shift Ins (INS) | VAF 43/263 reads (16%) | called by mutect2, pindel, varscan2
- FH | c.1432A>C p.N478H | Missense Mutation (SNP) | VAF 52/430 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, varscan2
- FKBP5 | c.306A>G p.I102M | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- FREM3 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPLD1 | c.2273T>A p.V758E | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- GPR149 | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.107); called by muse, mutect2
- GRAMD1C | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- LURAP1L | c.135del p.S46Afs*48 | Frame Shift Del (DEL) | VAF 25/107 reads (23%) | called by mutect2, pindel, varscan2
- MUC16 | c.43068+1G>A p.X14356_splice | Splice Site (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- MUC16 | c.3520C>T p.Q1174* | Nonsense Mutation (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- NF2 | c.1050_1057del p.R351Gfs*2 | Frame Shift Del (DEL) | VAF 97/494 reads (20%) | called by mutect2, pindel, varscan2
- NTSR1 | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- ODF3B | c.109+1del p.X37_splice | Splice Site (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- OVCH1 | c.282-1G>A p.X94_splice | Splice Site (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- P2RX2 | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- PPP6R2 | c.2530G>A p.V844M (on ENST00000216061 / NM_001365836.1; = p.V810M on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.408); called by muse, mutect2
- PROB1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RASA1 | c.2345-2A>G p.X782_splice | Splice Site (SNP) | VAF 44/264 reads (17%) | called by muse, mutect2, varscan2
- SCN2A | c.4657del p.D1553Mfs*7 | Frame Shift Del (DEL) | VAF 33/234 reads (14%) | called by mutect2, pindel, varscan2
- SLC17A1 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC17A9 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 15/127 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SLC5A2 | c.1792_1792+14del p.X598_splice | Splice Site (DEL) | VAF 32/434 reads (7%) | called by mutect2, pindel
- SOST | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 80/375 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- SYDE1 | c.1975G>T p.G659W | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D22A | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- UBE2Q2 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR74 | c.336G>T p.W112C | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- WRN | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 39/393 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF28 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2
- ZNF30 | c.796G>T p.G266W | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF383 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZNF808 | c.2015T>C p.L672P | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2
- ALMS1 | c.9495C>T p.F3165= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as rs45607436, COSV52526621; called by muse, mutect2
- BIRC6 | c.282C>T p.I94= | Silent (SNP) | VAF 23/446 reads (5%) | called by muse, mutect2
- CHRDL2 | c.372C>T p.F124= | Silent (SNP) | VAF 10/219 reads (5%) | called by muse, mutect2
- COL4A3 | c.1443T>C p.Y481= | Silent (SNP) | VAF 45/393 reads (11%) | catalogued as CM1511096; called by muse, mutect2, varscan2
- DACT2 | c.1854G>A p.R618= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- DYNC1H1 | c.7272A>G p.Q2424= | Silent (SNP) | VAF 22/353 reads (6%) | catalogued as rs749295312; called by muse, mutect2
- FILIP1L | c.3102C>T p.V1034= (on ENST00000354552 / NM_182909.3; = p.V794= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- HAP1 | c.1032G>A p.E344= | Silent (SNP) | VAF 47/245 reads (19%) | called by muse, mutect2, varscan2
- IGSF22 | c.117C>A p.V39= | Silent (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- IL20RB | c.438C>A p.T146= | Silent (SNP) | VAF 13/236 reads (6%) | catalogued as COSV59047492; called by muse, mutect2
- ITIH1 | c.2205C>T p.I735= | Silent (SNP) | VAF 14/316 reads (4%) | catalogued as COSV56256758; called by muse, mutect2
- LRG1 | c.546G>A p.G182= | Silent (SNP) | VAF 46/222 reads (21%) | catalogued as rs774998596, COSV56703636; called by muse, mutect2, varscan2
- MMP27 | c.1131T>C p.D377= | Silent (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- MUC5B | c.9033C>T p.I3011= | Silent (SNP) | VAF 15/248 reads (6%) | called by muse, mutect2
- MYCBPAP | c.2758C>T p.L920= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- MYO18A | c.609C>G p.V203= | Silent (SNP) | VAF 9/200 reads (5%) | called by muse, mutect2
- N4BP2L2 | c.1113A>G p.R371= | Silent (SNP) | VAF 32/253 reads (13%) | catalogued as rs778471419; called by muse, mutect2, varscan2
- NLRP7 | c.1275G>A p.A425= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as rs771909550, COSV60179047; called by muse, mutect2
- PLLP | c.537C>T p.G179= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs750896722; called by muse, varscan2
- RAB11FIP1 | c.1188G>A p.P396= | Silent (SNP) | VAF 26/269 reads (10%) | catalogued as rs780045862; called by muse, mutect2
- RAB3GAP2 | c.2523G>T p.A841= | Silent (SNP) | VAF 28/266 reads (11%) | catalogued as rs201668103, COSV62783839; called by muse, mutect2
- RARS1 | c.21G>A p.E7= | Silent (SNP) | VAF 48/196 reads (24%) | catalogued as rs1430275228; called by muse, mutect2, varscan2
- RFTN2 | c.498T>C p.S166= | Silent (SNP) | VAF 23/209 reads (11%) | catalogued as rs1291506570; called by muse, mutect2, varscan2
- SEMA3D | c.2169A>G p.P723= | Silent (SNP) | VAF 69/379 reads (18%) | catalogued as rs1421557413; called by muse, mutect2, varscan2
- SETD5 | c.3345G>T p.V1115= | Silent (SNP) | VAF 37/441 reads (8%) | catalogued as rs771111400; called by muse, mutect2
- SIRPA | c.1356G>A p.E452= | Silent (SNP) | VAF 50/266 reads (19%) | called by muse, mutect2, varscan2
- SLC5A1 | c.1914G>A p.K638= | Silent (SNP) | VAF 91/454 reads (20%) | catalogued as COSV56684575; called by muse, mutect2, varscan2
- UNKL | c.984C>T p.L328= | Silent (SNP) | VAF 15/350 reads (4%) | catalogued as rs936514525; called by muse, mutect2
- ZSCAN25 | c.624C>T p.P208= | Silent (SNP) | VAF 28/195 reads (14%) | catalogued as rs765554490, COSV53552221; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1047-3059T>C | Intron (SNP) | VAF 50/248 reads (20%) | called by muse, mutect2, varscan2
- B3GNT4 | c.*621G>C | 3'UTR (SNP) | VAF 24/502 reads (5%) | catalogued as rs968285691; called by muse, mutect2
- B3GNT4 | c.*1216G>C | 3'UTR (SNP) | VAF 28/428 reads (7%) | called by muse, mutect2
- BRSK2 | c.*169C>A | 3'UTR (SNP) | VAF 33/286 reads (12%) | called by muse, mutect2, varscan2
- C5orf17 | n.296C>T | RNA (SNP) | VAF 6/48 reads (13%) | catalogued as rs1395851798; called by muse, mutect2, varscan2
- FAM90A20P | n.488C>T | RNA (SNP) | VAF 42/476 reads (9%) | catalogued as rs755897868; called by muse, mutect2
- FLYWCH1 | c.1514-715C>G | Intron (SNP) | VAF 25/138 reads (18%) | catalogued as rs986630007; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847967 G>C | 5'Flank (SNP) | VAF 26/398 reads (7%) | called by muse, mutect2
- KLC1 | c.*7475A>T | 3'UTR (SNP) | VAF 28/404 reads (7%) | called by muse, mutect2
- MMAB | c.*2387G>T | 3'UTR (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- MPRIP | c.2163+4305C>T | Intron (SNP) | VAF 14/260 reads (5%) | catalogued as rs931696326, COSV57926783; called by muse, mutect2
- NBPF22P | n.1296G>C | RNA (SNP) | VAF 82/445 reads (18%) | called by mutect2, varscan2
- TMEM135 | c.*2677C>G | 3'UTR (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- TMEM80 | c.71+36G>C | Intron (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- TPCN1 | c.1706+54C>T | Intron (SNP) | VAF 13/123 reads (11%) | catalogued as rs755121441; called by muse, mutect2
- WT1 | chr11:32439367 G>A | 5'Flank (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
